Somatic mutation profile of tumor specimen TCGA-SG-A6Z7-01A (aliquot TCGA-SG-A6Z7-01A-12D-A32I-09) from TCGA case TCGA-SG-A6Z7, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 44.3 years (16,188 days).
Specimen TCGA-SG-A6Z7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4fb373b-dbb6-4779-a278-32e4fef06057.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SG-A6Z7-11A (Solid Tissue Normal), aliquot TCGA-SG-A6Z7-11A-21D-A32I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d00c8a60-13a7-40db-ac57-97b59264c7e5

The open-access MAF lists 48 somatic variants for this specimen: 38 protein-altering or splice-affecting, 8 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 8, Nonsense Mutation 2, 3'Flank 1, Nonstop Mutation 1, 5'Flank 1, Splice Site 1, Translation Start Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABT1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.058); catalogued as rs782466757, COSV99223404; called by muse, mutect2, varscan2
- CALCB | c.316A>T p.S106C | Missense Mutation (SNP) | VAF 33/41 reads (80%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.819); catalogued as COSV100158173; called by muse, mutect2, varscan2
- CCDC27 | c.1728G>C p.E576D | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV99623065; called by muse, mutect2, varscan2
- CKLF | c.245T>A p.I82N | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99862725; called by muse, mutect2, varscan2
- CNGB1 | c.1778C>A p.S593Y | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99212405; called by muse, mutect2
- CTCF | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 49/111 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV99866850; called by muse, mutect2, varscan2
- CTR9 | c.19G>C p.E7Q | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV100797551; called by muse, mutect2, varscan2
- DSE | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.255); catalogued as COSV100528857; called by muse, mutect2
- ELL2 | c.443G>C p.R148P | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99428000; called by muse, mutect2, varscan2
- FAT1 | c.1616G>A p.R539H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs368802187, COSV71674089; called by muse, mutect2, varscan2
- HOXC8 | c.230G>T p.C77F | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99237031; called by muse, mutect2, varscan2
- HSD17B11 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100839651; called by muse, mutect2
- IL12RB2 | c.290C>T p.T97I | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV99255822; called by muse, mutect2, varscan2
- INSL4 | c.310T>A p.L104M | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.766); catalogued as COSV99497270; called by muse, mutect2, varscan2
- IVL | c.1247A>T p.Q416L | Missense Mutation (SNP) | VAF 7/170 reads (4%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); catalogued as COSV100908255, COSV100908310; called by muse, mutect2
- LCE1A | c.242G>A p.R81K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0.001); catalogued as COSV58727006; called by muse, varscan2
- LRRK2 | c.2815A>G p.I939V | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV100111466; called by muse, mutect2, varscan2
- MOV10 | c.1663C>T p.P555S | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.897); catalogued as COSV100659815, COSV62492921; called by muse, mutect2, varscan2
- MRTFB | c.1430C>T p.S477L | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs866512883, COSV100371956; called by muse, mutect2, varscan2
- MTHFS | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 40/84 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV99358390; called by muse, mutect2, varscan2
- NOL10 | c.395G>C p.R132T | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100630353; called by muse, mutect2, varscan2
- OBI1 | c.1624G>C p.D542H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99932687; called by muse, mutect2, varscan2
- OR2F1 | c.954A>G p.*318Wext*6 | Nonstop Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV101231342; called by muse, mutect2, varscan2
- PASK | c.3042G>A p.W1014* | Nonsense Mutation (SNP) | VAF 53/94 reads (56%) | catalogued as COSV52154933, COSV99300460; called by muse, mutect2, varscan2
- PASK | c.2918G>A p.R973K | Missense Mutation (SNP) | VAF 37/76 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52149779, COSV99299153; called by muse, mutect2, varscan2
- PLEKHG4B | c.1231A>G p.T411A (on ENST00000283426; = p.T767A on NM_052909.5) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.111); catalogued as COSV99361320; called by muse, mutect2
- PPARGC1A | c.251A>T p.N84I | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV99338896; called by muse, mutect2, varscan2
- PRKDC | c.6950C>G p.A2317G | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV100043488; called by muse, mutect2, varscan2
- SLC4A1 | c.2689G>T p.E897* | Nonsense Mutation (SNP) | VAF 18/52 reads (35%) | catalogued as COSV99293778; called by muse, mutect2, varscan2
- SLIT2 | c.3772G>A p.G1258S | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.893); catalogued as COSV99881472, COSV99888190; called by muse, mutect2, varscan2
- SLITRK2 | c.1417C>A p.L473I | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100158340; called by muse, mutect2, varscan2
- SYNE2 | c.3353+1G>A p.X1118_splice | Splice Site (SNP) | VAF 8/100 reads (8%) | catalogued as COSV59954736; called by muse, mutect2
- TOX | c.866G>A p.G289D | Missense Mutation (SNP) | VAF 16/256 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100813178; called by muse, mutect2
- TRDN | c.787C>G p.Q263E | Missense Mutation (SNP) | VAF 53/83 reads (64%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.473); catalogued as COSV62136072; called by muse, mutect2, varscan2
- TTLL8 | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 5/85 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV99838770; called by muse, mutect2
- VCP | c.1550A>G p.Y517C | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100734394; called by muse, mutect2, varscan2
- ZFC3H1 | c.1102G>C p.E368Q | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV101110738; called by muse, mutect2, varscan2
- ZSWIM4 | c.573del p.L192Sfs*4 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- FANK1 | c.981C>G p.V327= | Silent (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100903676; called by muse, mutect2, varscan2
- GPHN | c.2157C>T p.Y719= (on ENST00000315266 / NM_001377519.1; = p.Y752= on NM_020806.5) | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs1443875641, COSV100017414; called by muse, mutect2, varscan2
- KCNA3 | c.1620C>T p.S540= | Silent (SNP) | VAF 34/75 reads (45%) | catalogued as rs756586190, COSV63901223; called by muse, mutect2, varscan2
- LCE2B | c.273C>T p.C91= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as COSV100909358; called by muse, varscan2
- MBOAT7 | c.366G>T p.L122= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV99825149; called by muse, mutect2, varscan2
- MYH3 | c.5556G>A p.T1852= | Silent (SNP) | VAF 38/40 reads (95%) | catalogued as rs753287976, COSV99879090; called by muse, mutect2, varscan2
- PIDD1 | c.792C>T p.L264= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV100758837; called by muse, mutect2
- TIPARP | c.864C>T p.H288= | Silent (SNP) | VAF 16/31 reads (52%) | catalogued as COSV99904060; called by muse, mutect2, varscan2
- ABCA2 | chr9:137033075 G>T | 5'Flank (SNP) | VAF 7/44 reads (16%) | called by muse, mutect2, varscan2
- EMC3-AS1 | chr3:10007528 G>A | 3'Flank (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
